Somatic mutation profile of tumor specimen TCGA-22-1011-01A (aliquot TCGA-22-1011-01A-01D-1521-08) from TCGA case TCGA-22-1011, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.2 years (26,732 days).
Specimen TCGA-22-1011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 143b82d6-62ad-4275-9f0e-d05a3d818635.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1011-11A (Solid Tissue Normal), aliquot TCGA-22-1011-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13a14377-465d-42bb-b90d-7e95afc37c74

The open-access MAF lists 101 somatic variants for this specimen: 76 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 24, Nonsense Mutation 6, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD2 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58052460; called by muse, mutect2
- AFAP1L1 | c.285A>C p.K95N | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.057); catalogued as COSV57045828, COSV99696249; called by muse, mutect2, varscan2
- AGL | c.1769G>C p.G590A | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54053895; called by muse, varscan2
- AKAP9 | c.9380G>T p.G3127V (on ENST00000359028; = p.G3103V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/700 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV62349179; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4720G>A p.D1574N | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.984); catalogued as rs1010868916, COSV51850403; called by muse, mutect2, varscan2
- AQR | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV50037282; called by muse, mutect2, varscan2
- ASXL2 | c.3715G>C p.E1239Q | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.343); catalogued as COSV55460559; called by muse, mutect2, varscan2
- C3orf70 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.09); catalogued as COSV100621369, COSV58588488; called by muse, mutect2
- CCDC88A | c.1047A>T p.L349F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55063695; called by muse, mutect2, varscan2
- CLRN1 | c.386A>G p.E129G (on ENST00000327047 / NM_174878.3; = p.E53G on NM_052995.2) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV55805901; called by muse, mutect2, varscan2
- DAB2 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 52/246 reads (21%) | catalogued as COSV57915563; called by muse, mutect2
- DNAH2 | c.4807G>C p.E1603Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as COSV66720966; called by muse, mutect2
- DSPP | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.188); catalogued as rs773490979, COSV56808618; called by muse, mutect2, varscan2
- DST | c.8415G>C p.L2805F | Missense Mutation (SNP) | VAF 63/425 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99755566; called by muse, mutect2, varscan2
- DYNC2LI1 | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.229); catalogued as COSV53183890; called by muse, mutect2, varscan2
- EWSR1 | c.1200C>G p.I400M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV58424799; called by muse, mutect2, varscan2
- FAT3 | c.8303A>G p.D2768G | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV53125975; called by muse, varscan2
- FETUB | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs773072487, COSV54006098; called by muse, mutect2, varscan2
- GALNT16 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs774434799, COSV61886431; called by muse, mutect2
- GPAA1 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1554763752, COSV100284179, COSV60155983; called by muse, mutect2, varscan2
- HIVEP1 | c.6511G>C p.E2171Q | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV65102523; called by muse, mutect2, varscan2
- IL12B | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.026); catalogued as COSV51455271, COSV99180371; called by muse, mutect2, varscan2
- JAZF1 | c.658C>G p.Q220E | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV52239460; called by muse, mutect2, varscan2
- KANSL1L | c.2455G>C p.E819Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55993297; called by muse, mutect2
- KCTD10 | c.467C>A p.S156* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV57327231; called by muse, mutect2, varscan2
- KDM1B | c.1760C>T p.A587V (on ENST00000449850; = p.A355V on NM_153042.4) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.596); catalogued as COSV52811752; called by muse, mutect2, varscan2
- KMT2E | c.3082G>C p.D1028H | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV57575086, COSV99996290; called by muse, mutect2, varscan2
- L3MBTL3 | c.1712G>C p.R571T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs749202131, COSV62386711; called by muse, mutect2, varscan2
- LAMA1 | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67538966; called by muse, mutect2, varscan2
- LRP1B | c.1296T>A p.D432E | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV67234492; called by muse, mutect2, varscan2
- MAGEA3 | c.438C>G p.F146L | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV64756281; called by muse, mutect2, varscan2
- MAPKAP1 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.973); catalogued as COSV56369450; called by muse, mutect2, varscan2
- MSH5 | c.2220C>G p.F740L | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV65173515, COSV65173614; called by muse, mutect2, varscan2
- MYH7B | c.5863G>C p.E1955Q | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV52680991; called by muse, mutect2, varscan2
- MYO9A | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 36/204 reads (18%) | catalogued as COSV61852748; called by muse, mutect2, varscan2
- MYOM2 | c.4209G>C p.M1403I | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV50723601; called by muse, mutect2, varscan2
- OR2D2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143950338; called by muse, mutect2, varscan2
- OR51V1 | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV58314912, COSV58315461; called by muse, mutect2, varscan2
- PAM | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57213011, COSV57214744; called by muse, mutect2, varscan2
- PARD3 | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 30/168 reads (18%) | catalogued as COSV60752436; called by muse, mutect2, varscan2
- PCDHB8 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 26/657 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50778230; called by muse, mutect2
- PDE8A | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs750948067, COSV59637810; called by muse, mutect2, varscan2
- PDPR | c.951G>C p.K317N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.099); catalogued as COSV55353247; called by muse, mutect2
- PHF2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV63681552; called by muse, mutect2, varscan2
- PIWIL2 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.557); catalogued as COSV63252186; called by muse, mutect2, varscan2
- PLA2G2E | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as rs754249570, COSV64290641; called by muse, mutect2, varscan2
- PLCE1 | c.4672C>T p.Q1558* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as COSV53355467; called by muse, mutect2, varscan2
- PLCG2 | c.1337A>T p.Q446L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63871105; called by muse, mutect2, varscan2
- PSG6 | c.271G>C p.G91R | Missense Mutation (SNP) | VAF 72/560 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51833661, COSV51834205; called by muse, mutect2, varscan2
- PTPN14 | c.2071C>G p.Q691E | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100872395, COSV65284930; called by muse, varscan2
- PXDNL | c.1183C>G p.R395G | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV62488514, COSV62490154; called by muse, mutect2, varscan2
- RAB4A | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774886245, COSV64207646; called by muse, mutect2, varscan2
- RASSF9 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745825535, COSV63432828; called by muse, mutect2, varscan2
- SAGE1 | c.314-1G>T p.X105_splice | Splice Site (SNP) | VAF 27/90 reads (30%) | catalogued as COSV61011845, COSV61012292, COSV61014394; called by muse, mutect2, varscan2
- SAMD9 | c.3988G>C p.E1330Q | Missense Mutation (SNP) | VAF 53/1062 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV66073390, COSV66076101; called by muse, mutect2
- SEMA3G | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV51596235; called by muse, mutect2, varscan2
- SF3B2 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV57698197; called by muse, mutect2, varscan2
- SIK3 | c.2602G>A p.A868T (on ENST00000445177 / NM_001366686.2; = p.A826T on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV52616765; called by muse, mutect2, varscan2
- SLC25A47 | c.327+1G>A p.X109_splice | Splice Site (SNP) | VAF 9/79 reads (11%) | catalogued as rs202110884; called by muse, mutect2, varscan2
- SLC45A2 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV56872610; called by muse, mutect2, varscan2
- SLC4A2 | c.1223C>G p.S408C | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV59656828; called by muse, mutect2, varscan2
- STARD13 | c.515C>T p.P172L (on ENST00000336934 / NM_001243476.3; = p.P54L on NM_052851.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs752378877, COSV55232426; called by muse, mutect2, varscan2
- TLR4 | c.161T>G p.F54C (on ENST00000355622 / NM_138554.5; = p.F14C on NM_003266.4) | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.568); catalogued as COSV62923543; called by muse, mutect2, varscan2
- TPRN | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV58808003; called by muse, mutect2, varscan2
- TRIM37 | c.2439G>C p.L813F | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51885130; called by muse, mutect2, varscan2
- UBA1 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); catalogued as COSV60113393; called by muse, mutect2, varscan2
- UGT3A1 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs1190707099, COSV57099228; called by muse, mutect2
- USP9Y | c.4105G>C p.E1369Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.222); catalogued as COSV59099669; called by muse, mutect2
- VPS35 | c.2366C>A p.P789Q | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV54479440; called by muse, mutect2, varscan2
- ZFP14 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV54202907; called by muse, mutect2, varscan2
- ZNF570 | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV57579501; called by muse, mutect2, varscan2
- ZNF571 | c.1390C>G p.Q464E | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.392); catalogued as COSV60733547; called by muse, mutect2, varscan2
- ZNF571 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as COSV60733565; called by muse, mutect2, varscan2
- DMRT3 | c.165_178del p.E56Hfs*95 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel*, varscan2
- G3BP1 | c.57_58dup p.Y20Ffs*5 | Frame Shift Ins (INS) | VAF 33/208 reads (16%) | called by mutect2, pindel, varscan2
- IGKV1D-42 | c.203T>A p.L68H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- AC008397.2 | c.1212G>A p.L404= | Silent (SNP) | VAF 32/231 reads (14%) | catalogued as COSV53207620; called by muse, mutect2, varscan2
- ANKS4B | c.1167G>A p.L389= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as COSV61139396; called by muse, mutect2, varscan2
- APOC1 | c.9C>G p.L3= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2
- BLK | c.705G>A p.E235= | Silent (SNP) | VAF 29/179 reads (16%) | catalogued as COSV52053081; called by muse, mutect2, varscan2
- CAMSAP3 | c.1395C>A p.I465= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV50337607; called by muse, mutect2, varscan2
- DCDC2 | c.948A>T p.A316= | Silent (SNP) | VAF 41/285 reads (14%) | catalogued as COSV65829097; called by muse, mutect2, varscan2
- FXYD5 | c.150C>G p.V50= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV54343212; called by muse, mutect2, varscan2
- GPR37 | c.1080C>T p.F360= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV58257474; called by muse, mutect2, varscan2
- HAGHL | c.15C>T p.V5= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV52402790; called by muse, mutect2, varscan2
- HRH1 | c.399C>T p.L133= | Silent (SNP) | VAF 36/235 reads (15%) | catalogued as COSV67955573; called by muse, mutect2, varscan2
- HS1BP3 | c.369C>T p.A123= | Silent (SNP) | VAF 50/344 reads (15%) | catalogued as rs771544273, COSV58313485; called by muse, mutect2, varscan2
- KIF13A | c.3681A>T p.T1227= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV52454745; called by muse, mutect2, varscan2
- LTBP1 | c.3147A>T p.A1049= (on ENST00000404816 / NM_206943.4; = p.A723= on NM_000627.4) | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV55380900; called by muse, mutect2, varscan2
- PRDM4 | c.703C>T p.L235= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV57306232; called by muse, mutect2, varscan2
- PYGO1 | c.507C>T p.V169= | Silent (SNP) | VAF 28/193 reads (15%) | catalogued as COSV57348268; called by muse, mutect2, varscan2
- SALL1 | c.1053G>A p.P351= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs969243759, COSV51759309; called by muse, mutect2, varscan2
- SCNN1B | c.1650C>T p.I550= | Silent (SNP) | VAF 48/400 reads (12%) | catalogued as COSV56305825; called by muse, varscan2
- SLC13A1 | c.1752G>T p.S584= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs150844958, COSV52012990; called by muse, mutect2, varscan2
- SLC51A | c.324C>T p.I108= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as rs371651472; called by muse, varscan2
- SPDYC | c.591C>T p.V197= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs930975462, COSV65865312; called by muse, varscan2
- SPTBN4 | c.246C>T p.I82= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs761370440, COSV58951982; called by muse, mutect2, varscan2
- VASN | c.900C>T p.F300= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV52031097; called by muse, mutect2, varscan2
- ZNF318 | c.3048G>A p.S1016= | Silent (SNP) | VAF 53/325 reads (16%) | catalogued as rs773080896, COSV58933639; called by muse, mutect2, varscan2
- ZNF780B | c.1035G>C p.L345= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as COSV55465262; called by muse, mutect2, varscan2
- XIST | n.8511T>C | RNA (SNP) | VAF 54/168 reads (32%) | called by muse, mutect2, varscan2
